Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4G2, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4G2-01A (Primary Tumor).

[page 1 of 2]
Stomach, subtotal gastrectomy:

Advanced gastric carcinoma

(Muc2(-)/Muc5AC(+)/Muc6(-)/CD10(-)/cERB2(-).G type)

1. Location : lower third, Center at antrum, anterior wall

2. Gross type : Borrmann type 2

3. Histologic type : poorly differentiated carcinoma (non-solid type)
with prominent lymphoid stroma (LELC-like carcinoma)

>> tubular moderately differentiated carcinoma (about 20% of the tumor mass)

<Addendum>

Final diagnosis: stomach adenocarcinoma, diffuse type.

4. Histologic type : diffuse

5. Growth pattern: mixed expanding and infiltrative growth pattern

6. Size : 5.8x4.5 cm

7. Depth of invasion: invades subserosa (pT3).

8. Resection margin: free from carcinoma
safety margin: distal 6.3 cm, proximal 8.9 cm

9. Lymph node metastasis :
metastasis to 2 out of 63 regional lymph nodes (pN1)
(lesser curvature 0/43 : greater curvature 2/20)

10. Lymphatic invasion : not identified

11. Venous invasion : not identified

12. Perineural invasion : present, mild

13. Associated finding: peritumoral lymphocytic infiltration, marked

Specimen labeled as Anvil ring, biopsy: No tumor.

Lymph node, 14V, biopsy: No tumor (0/2).

Lymph node, biopsy: No tumor (0/1).

Lymph node, portal vein, biopsy: No tumor (0/1).

Immunohistochemistry : CD10, MUC2, MUC5ac, MUC6, C-erb B2

ICD-O-3

adenocarcinoma, diffuse type 8145/3

Site: stomach, antrum C16.3

fw 9/27/12

fw 9/27/12

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

This form is to be completed when the pathologic diagnosis on the initial pathology report for a case does not match the diagnosis on the TCGA Case Quality Control Form. The pathologic diagnosis on the initial pathology report for a case should be documented on the TCGA Case Quality Control Form.

Tissue Source Site (TSS): Stomach adenocarcinoma TSS Identifier:

Completed By:

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Stomach: Poorly Differentiated Carcinoma (non-solid type) w/Prominent Lymphoid Stroma (lymphoepithelioma like carcinoma (LELC) and 20% tubular carcinoma), Diffuse	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF	Stomach Adenocarcinoma, Diffuse Type	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Original pathology report (for the whole resected specimen) mentioned 20% of tubular carcinoma, which was not found in TCGA top slide. Review of top slide confirmed that this tumor is a stomach adenocarcinoma-diffuse type (originally described as Stomach Poorly Differentiated Carcinoma (non-solid type) w/Prominent Lymphoid Stroma (lymphoepithelioma like carcinoma)	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	 	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 8615b262-f44d-463a-b5b0-51b262b10752 (TCGA-HU-A4G2.CD260608-B0C2-445B-B528-1673C9D1458D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).